Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A036, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A036-01A (Primary Tumor).

ICD-0-3

Adenocarcinoma, NOS 8140/3

Site: Rectum, NOS C20.9

fw 3/21/11

Internal Sample II

Diagnosis/Diagnoses:

Rectal resection specimen with fully developed diverticulosis in the proximal segment and aboral, ulcerated, moderately differentiated adenocarcinoma extending into the perirectal fat (G2). Tumor-free oral and aboral margins.

The clinically reported infiltration of the posterior bladder wall is not detectable microscopically in the available material. Accordingly the neoplasia may be classified histologically as category pT3.

A follow-up report will be issued on the histology of lymph nodes dissected out from the perirectal fatty tissue after clarification with acetone.

Follow-up report:

Numerous lymph nodes of up to 1.2 cm in size were dissected out from the pericolic fatty tissue in the vicinity of the tumor after clarification with acetone.

Of 30 lymph nodes embedded as samples, 18 exhibited metastatic infiltrates from the previously diagnosed adenocarcinoma or colon carcinoma.

In conclusion or in summary, therefore, a stage of pT3 pN2 (18/30) is obtained.

Source: NCI Genomic Data Commons file 6755412f-23f2-45c0-af5b-8c0b2d45e429 (TCGA-AG-A036.882191BC-6882-4B56-B100-5235ECEB6396.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).